Gene-level copy-number profile of tumor specimen TCGA-ZS-A9CF-01A from TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-ZS-A9CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a4fb35ba-746a-4519-a8d2-3d6790b414a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZS-A9CF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/016e9ead-943b-4010-848a-23056d070baf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 11,694; copy number 2: 43,331; copy number 3: 4,536; copy number 4: 190; copy number 5: 23; copy number 6: 11; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZS-A9CF-01A-11D-A381-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:96,199,840–96,521,717, 2 genes (within-gene range 0–1): UFL1-AS1, RN7SL797P.
- chr7:150,791,285–150,805,118, 2 genes: TMEM176B, TMEM176A.
- chr17:9,171,068–9,179,118, 1 gene: AC005695.1.
- chr22:50,597,152–50,801,309, 13 genes: U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,718,789–56,918,223, 3 genes, copy number 5: FYB2, AL360295.1, C8A.
- chr1:171,137,740–171,227,788, 3 genes, copy number 5: FMO6P, FMO2, AL021026.1.
- chr3:161,083,883–161,253,532, 3 genes, copy number 6 (within-gene range 3–6): B3GALNT1, NMD3, AC108738.1.
- chr6:3,831,933–3,894,292, 3 genes, copy number 6 (within-gene range 3–6): AL391422.3, AL391422.2, FAM50B.
- chr6:43,770,184–43,852,333, 5 genes, copy number 5: VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:78,604,467–78,946,440, 3 genes, copy number 6 (within-gene range 1–6): AL121718.1, AL450327.1, IRAK1BP1.
- chr8:100,380,486–100,464,613, 1 gene, copy number 6 (within-gene range 2–6): AP003472.1.
- chr8:100,427,559–100,432,726, 1 gene, copy number 6: AP003472.2.
- chr16:3,930,806–3,950,586, 1 gene, copy number 5: LINC02861.
- chr18:41,341,319–43,499,836, 15 genes, copy number 5–7: AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1.

Autosomal genes at a single copy (total copy number 1): 9,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
